Somatic mutation profile of tumor specimen TCGA-3B-A9HQ-01A (aliquot TCGA-3B-A9HQ-01A-11D-A387-09) from TCGA case TCGA-3B-A9HQ, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 66.8 years (24,386 days).
Specimen TCGA-3B-A9HQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0962e72-aa9c-4993-b65c-4124e7fe92b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HQ-10A (Blood Derived Normal), aliquot TCGA-3B-A9HQ-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a416b27f-c540-4d51-b1a1-4307b0d7bdcc

The open-access MAF lists 60 somatic variants for this specimen: 48 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Frame Shift Del 5, Splice Site 3, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.559+2del p.X187_splice | Splice Site (DEL) | VAF 14/28 reads (50%) | hotspot (GDC flag); catalogued as rs1567552459, CS114004, COSV52709511, COSV52900265, COSV53486980, COSV99478821; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ABCD1 | c.1849C>G p.R617G | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CD051288, CM940041, CM960044, HM080121, COSV99497213, COSV99497448; called by muse, mutect2, varscan2
- ANGPT4 | c.125A>C p.H42P | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.062); catalogued as rs1210384122, COSV101124697; called by muse, mutect2
- ANGPT4 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV101124698; called by muse, mutect2
- AOPEP | c.550A>G p.R184G | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs1441806451, COSV99468083; called by muse, mutect2, varscan2
- BNC1 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100597088; called by muse, mutect2, varscan2
- CENPU | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1238500794, COSV99859863; called by muse, mutect2, varscan2
- CHL1 | c.301T>A p.S101T | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs926392263, COSV99850796; called by muse, mutect2, varscan2
- CR2 | c.2711C>G p.A904G | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV100889592; called by muse, mutect2, varscan2
- DNAH7 | c.1833+1G>T p.X611_splice | Splice Site (SNP) | VAF 28/66 reads (42%) | catalogued as COSV100414699; called by muse, mutect2, varscan2
- EPHA5 | c.2131G>T p.V711L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV99898087; called by muse, mutect2, varscan2
- ESPL1 | c.5062C>T p.P1688S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99229170; called by muse, mutect2, varscan2
- GRAMD4 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs1293213199, COSV100730415; called by mutect2, varscan2
- HP | c.384C>A p.N128K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100577490; called by muse, mutect2, varscan2
- HS3ST1 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.323); catalogued as rs202015819; called by muse, mutect2, varscan2
- IL17A | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs760902102, COSV60684014; called by muse, mutect2, varscan2
- KCNB2 | c.447C>A p.N149K | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV101578734, COSV73048698; called by muse, mutect2, varscan2
- KYNU | c.902+1G>C p.X301_splice | Splice Site (SNP) | VAF 23/65 reads (35%) | catalogued as CS142922, COSV51581424, COSV99933063; called by muse, mutect2, varscan2
- LARP1 | c.1978G>T p.D660Y (on ENST00000518297 / NM_033551.3; = p.D583Y on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765076218, COSV100303679, COSV100304002, COSV60425194; called by muse, mutect2, varscan2
- LRRK1 | c.1424T>A p.L475H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99439044; called by muse, mutect2, varscan2
- OR51E1 | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.588); catalogued as COSV101211439; called by muse, mutect2, varscan2
- OR5M10 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV101595877; called by muse, mutect2, varscan2
- OTOP3 | c.1413G>T p.Q471H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.482); catalogued as rs1159102893, COSV100172763; called by muse, mutect2, varscan2
- PPP1R26 | c.1042A>G p.K348E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV100778041; called by muse, mutect2, varscan2
- PPRC1 | c.349T>A p.L117I | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.313); catalogued as COSV99531559; called by muse, mutect2, varscan2
- PWWP2B | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV100535713; called by muse, mutect2, varscan2
- QRICH2 | c.2814C>A p.D938E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV99429063; called by muse, mutect2
- SACS | c.7696G>A p.D2566N | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV101207373; called by muse, mutect2, varscan2
- SCUBE1 | c.1735C>A p.Q579K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100683112; called by muse, mutect2, varscan2
- SF3A2 | c.1052A>G p.H351R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.068); catalogued as COSV99677719; called by muse, mutect2, varscan2
- SLC27A6 | c.1724A>G p.H575R | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99322546; called by muse, mutect2, varscan2
- SLC5A1 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99833337; called by muse, mutect2, varscan2
- SLC7A14 | c.1681A>G p.T561A | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV99200446; called by muse, mutect2, varscan2
- SP110 | c.1779G>C p.K593N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV51246535, COSV99283281; called by muse, mutect2, varscan2
- SPTBN4 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.971); catalogued as COSV100150598; called by muse, mutect2, varscan2
- TEC | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs750190240, COSV67405584; called by muse, mutect2, varscan2
- TEX13B | c.713C>A p.A238E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100258326; called by muse, mutect2, varscan2
- TMCO4 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs144254063; called by muse, mutect2, varscan2
- TRIOBP | c.3934G>A p.G1312R | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.106); catalogued as rs1016862310, COSV100730788; called by muse, mutect2, varscan2
- URB2 | c.4179G>T p.L1393F | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99270992; called by muse, mutect2
- ZAP70 | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs200679935, COSV53853717; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFPM2 | c.2838T>G p.S946R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV101023150; called by muse, mutect2, varscan2
- CNTNAP5 | c.2118del p.R706Sfs*19 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- COL22A1 | c.2645del p.P882Rfs*120 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- FRK | c.550del p.S184Qfs*3 | Frame Shift Del (DEL) | VAF 30/116 reads (26%) | called by pindel, varscan2
- PHKB | c.439_441del p.T147del | In Frame Del (DEL) | VAF 14/36 reads (39%) | called by pindel, varscan2
- RGPD2 | c.5138del p.L1713* | Frame Shift Del (DEL) | VAF 22/38 reads (58%) | called by mutect2, varscan2
- TUT7 | c.2929del p.D977Tfs*11 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.4084C>T p.L1362= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs536763405, COSV101000455; called by mutect2, varscan2
- ANKRD24 | c.1566G>A p.E522= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99517310; called by muse, mutect2, varscan2
- CDH6 | c.2256G>A p.S752= | Silent (SNP) | VAF 34/65 reads (52%) | catalogued as rs754696790, COSV99418694; called by muse, mutect2, varscan2
- CLN6 | c.387G>A p.V129= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99992581; called by muse, mutect2, varscan2
- DMBT1 | c.459A>G p.G153= | Silent (SNP) | VAF 53/79 reads (67%) | catalogued as COSV100352671; called by muse, mutect2, varscan2
- HAUS7 | c.918C>T p.P306= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV100444069, COSV57849013; called by muse, mutect2, varscan2
- LRRC42 | c.738C>T p.I246= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV100066429; called by muse, mutect2, varscan2
- LRRK1 | c.1425C>T p.L475= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1242827493, COSV99439048; called by muse, mutect2, varscan2
- MYBPH | c.75C>T p.P25= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV99703895; called by muse, mutect2, varscan2
- SERPINF2 | c.1221C>T p.S407= | Silent (SNP) | VAF 25/34 reads (74%) | catalogued as rs746295482, COSV100131881, COSV60665128; called by muse, mutect2, varscan2
- ZHX2 | c.2211C>T p.L737= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100072859; called by muse, mutect2, varscan2
- ZNF658B | n.860G>T | RNA (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
